Somatic mutation profile of tumor specimen TCGA-DX-A6B7-01A (aliquot TCGA-DX-A6B7-01A-11D-A307-09) from TCGA case TCGA-DX-A6B7, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 55.8 years (20,365 days).
Specimen TCGA-DX-A6B7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c4899204-e407-4189-88b7-7c8e8978662f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6B7-10A (Blood Derived Normal), aliquot TCGA-DX-A6B7-10A-01D-A307-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2d00089e-81b0-4e80-a159-5f29080fe1ce

The open-access MAF lists 32 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 19/22 reads (86%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BAHCC1 | c.5981C>T p.P1994L | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs374689780; called by muse, mutect2, varscan2
- FRMPD4 | c.3186T>G p.S1062R | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.012); catalogued as COSV101042082; called by muse, varscan2
- FZD5 | c.571A>T p.K191* | Nonsense Mutation (SNP) | VAF 14/36 reads (39%) | catalogued as COSV99776195; called by muse, mutect2, varscan2
- HIPK1 | c.2847G>C p.L949F | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as COSV100478359; called by muse, mutect2, varscan2
- HIPK1 | c.3410G>A p.G1137D (on ENST00000369558 / NM_001369806.1; = p.G743D on NM_181358.2) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV100478363; called by muse, varscan2
- KIF5C | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101381931; called by muse, mutect2
- LGALS12 | c.260G>C p.C87S | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99736828; called by muse, mutect2, varscan2
- PCNX3 | c.5066G>A p.S1689N | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.757); catalogued as rs375106937; called by muse, varscan2
- RBM6 | c.656A>C p.D219A | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV56481880, COSV99804457; called by muse, mutect2, varscan2
- RXFP3 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57504071; called by muse, mutect2, varscan2
- SCN2A | c.2245A>G p.K749E | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV99330013; called by muse, mutect2, varscan2
- STEAP1 | c.753C>G p.H251Q | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as COSV99787505; called by muse, mutect2, varscan2
- TENT5A | c.796G>C p.G266R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100198750; called by muse, mutect2, varscan2
- UNC13A | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs950847565, COSV53195450; called by muse, mutect2, varscan2
- ZC3H12B | c.886G>T p.V296L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100161459, COSV59047071; called by muse, mutect2
- ARFGEF1 | c.2140_2141dup p.G716Efs*29 | Frame Shift Ins (INS) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- ATM | c.4207del p.S1403Afs*3 | Frame Shift Del (DEL) | VAF 10/63 reads (16%) | called by pindel, varscan2
- B3GNT6 | c.84G>T p.Q28H | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- FCGBP | c.11062A>C p.K3688Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FCGBP | c.4215T>A p.N1405K | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- GRIA1 | c.83-1G>A p.X28_splice | Splice Site (SNP) | VAF 4/30 reads (13%) | called by mutect2, varscan2
- BARHL2 | c.768C>T p.Y256= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs371535178; called by muse, mutect2, varscan2
- CLCN1 | c.1993C>T p.L665= | Silent (SNP) | VAF 60/146 reads (41%) | catalogued as COSV100577690; called by muse, mutect2, varscan2
- GSTA5 | c.69G>C p.L23= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV99489374; called by muse, mutect2, varscan2
- HIPK1 | c.3483G>C p.G1161= (on ENST00000369558 / NM_001369806.1; = p.G767= on NM_181358.2) | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV100478367; called by muse, varscan2
- KIF27 | c.138T>G p.T46= | Silent (SNP) | VAF 20/129 reads (16%) | catalogued as COSV99926624; called by muse, mutect2, varscan2
- PPP1R12A | c.1815A>G p.T605= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs374310208; called by muse, mutect2, varscan2
- RANBP17 | c.1068A>G p.R356= | Silent (SNP) | VAF 32/73 reads (44%) | catalogued as COSV101206054; called by muse, mutect2, varscan2
- SCFD1 | c.57G>A p.Q19= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as COSV99249277, COSV99249305; called by muse, mutect2, varscan2
- TRIOBP | c.6291G>A p.E2097= (on ENST00000644935 / NM_001039141.3; = p.E384= on NM_007032.5) | Silent (SNP) | VAF 21/33 reads (64%) | catalogued as COSV100462212; called by muse, mutect2, varscan2
- TRPM1 | c.1659C>T p.N553= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99855281; called by muse, mutect2, varscan2
